Gene-level copy-number profile of tumor specimen TCGA-VQ-A8E7-01B from TCGA case TCGA-VQ-A8E7, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 59.3 years (21,664 days).
Specimen TCGA-VQ-A8E7-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.ad624986-d25a-4874-87b2-6e6f4a14270c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A8E7-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a52ad86a-1a37-4a03-a052-de87e939190d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 46; copy number 1: 9,760; copy number 2: 42,124; copy number 3: 6,192; copy number 4: 1,515; copy number 5: 37; copy number 6: 104; copy number 10: 10; copy number 24: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A8E7-01B-11D-A40Z-01): tumor purity 0.66, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr9:21,321,300–22,824,213, 37 genes: IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 175 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:130,052,104–130,443,674, 1 gene, copy number 6 (within-gene range 4–6): ASAP1.
- chr8:130,162,972–131,144,948, 8 genes, copy number 6: AC103725.1, AC009682.1, AC139019.1, AC090987.1, ADCY8, AC103726.1, AC103726.2, AC087341.1.
- chr17:35,147,817–35,578,863, 36 genes, copy number 5 (within-gene range 2–5): UNC45B, AC022916.4, AC022916.2, AC022916.3, SLC35G3, AC022916.1, SLFN5, AC022706.1, AC060766.2, SLFN11, AC060766.3, AC060766.6, AC060766.4, AC060766.7, AC060766.5, AC060766.1, SLFN12, SLFN13, AC015911.4, SLFN12L, AC015911.7, SLFN12L, AC015911.5, E2F3P1, TAF5LP1, AC015911.3, TOMM20P2, AC015911.9, AC015911.2, SLFN14, AC015911.6, AC015911.8, AC015911.1, SNHG30, SNORD7, PEX12.
- chr17:35,596,904–35,597,128, 1 gene, copy number 5: AC004134.1.
- chr17:38,925,168–40,885,242, 95 genes, copy number 6 (broad region; genes not listed).
- chr17:41,363,498–41,848,384, 34 genes, copy number 10–24 (within-gene range 4–24): KRT33B, KRT34, KRT31, AC003958.2, KRT41P, KRT37, KRT38, KRT43P, KRT32, RNU2-32P, KRT35, KRT36, KRT13, AC019349.1, KRT15, MIR6510, KRT19, LINC00974, KRT9, KRT14, KRT16, KRT17, KRT42P, AC130686.1, EIF1, GAST, HAP1, RNA5SP442, RN7SL399P, JUP, P3H4, FKBP10, NT5C3B, KLHL10.

Autosomal genes at a single copy (total copy number 1): 7,378. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
